Somatic mutation profile of tumor specimen C3N-00743-01 (aliquot CPT0062940009) from CPTAC case C3N-00743, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.3 years (19,452 days).
Specimen C3N-00743-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4075193-0272-4573-8d52-3a9a0c04aef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00743-71 (Blood Derived Normal), aliquot CPT0063060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a067a61a-2006-410e-bb1e-c555891baa9b

The open-access MAF lists 440 somatic variants for this specimen: 296 protein-altering or splice-affecting, 94 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 94, Frame Shift Del 52, Intron 25, Frame Shift Ins 20, Nonsense Mutation 11, 3'UTR 10, Splice Site 6, In Frame Del 6, RNA 5, 5'UTR 5, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2273del p.L758* (on ENST00000272895 / NM_173076.3; = p.L440* on NM_015657.3) | Frame Shift Del (DEL) | VAF 53/330 reads (16%) | catalogued as rs1064794286; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CNGA3 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs137852608, CM980378, COSV55621988; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 176/595 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNK9 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 163/426 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867543866; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 72/466 reads (15%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 83/274 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 25/88 reads (28%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- AC006059.2 | c.1510C>A p.L504M | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.209); catalogued as COSV100045785; called by muse, mutect2
- ACTBL2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 22/334 reads (7%) | catalogued as rs775550635; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 48/73 reads (66%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADGRF1 | c.96dup p.E33Rfs*6 | Frame Shift Ins (INS) | VAF 38/152 reads (25%) | catalogued as rs771491120; called by mutect2, varscan2
- AGAP3 | c.446del p.P149Lfs*74 (on ENST00000622464; = p.P185Lfs*74 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 154/481 reads (32%) | catalogued as rs1563473506; called by mutect2, pindel, varscan2
- ANKRD30B | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 231/708 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769489567; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 169/546 reads (31%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- AR | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM970103; called by muse, mutect2, varscan2
- AXDND1 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as rs754952987, COSV62642121; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BAG6 | c.3028C>T p.R1010W (on ENST00000676571; = p.R963W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs758960107, COSV52988646; called by muse, mutect2, varscan2
- BAHCC1 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs782314841; called by muse, mutect2, varscan2
- BICRA | c.1320dup p.G441Rfs*233 | Frame Shift Ins (INS) | VAF 52/198 reads (26%) | catalogued as rs1361394574; called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 163/631 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs1361602917, COSV100863975; called by muse, mutect2, varscan2
- C19orf44 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs201667858; called by muse, mutect2
- C2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147553278; called by muse, mutect2, varscan2
- CACNA1G | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs866204450, COSV61720311; called by muse, mutect2, varscan2
- CASS4 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367625281; called by muse, mutect2, varscan2
- CBR3 | c.348dup p.A117Cfs*3 | Frame Shift Ins (INS) | VAF 26/122 reads (21%) | catalogued as rs761167907; called by mutect2, varscan2
- CC2D2A | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754586025, CM120109; called by muse, mutect2, varscan2
- CDC16 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1419216884, COSV52960178; called by muse, mutect2
- CDKL1 | c.548del p.P183Rfs*32 | Frame Shift Del (DEL) | VAF 97/377 reads (26%) | catalogued as rs766143608, COSV53583338; called by mutect2, pindel, varscan2
- CELSR3 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1278475307, COSV51142676; called by muse, mutect2, varscan2
- CEP164 | c.1854G>A p.M618I | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54039592; called by muse, mutect2
- CERCAM | c.559del p.Q187Rfs*84 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | catalogued as rs780407630, COSV65712087; called by mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | catalogued as rs1561489348; called by mutect2, pindel
- CLEC16A | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377731704; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs369752219; called by mutect2, varscan2
- COL5A2 | c.2392G>A p.G798S | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415764; called by muse, mutect2, varscan2
- CPO | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 157/541 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs144914072; called by muse, mutect2, varscan2
- CRY2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs760652914, COSV69889519; called by muse, mutect2, varscan2
- CSNK1A1L | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs748869443; called by muse, mutect2, varscan2
- CYFIP2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs747636391; called by muse, mutect2, varscan2
- DCX | c.945C>T p.D315= | Splice Region (SNP) | VAF 31/647 reads (5%) | catalogued as rs927836147; called by muse, mutect2
- DDX3X | c.1421G>A p.R474H (on ENST00000399959; = p.R475H on NM_001356.5) | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV67863186; called by muse, mutect2
- DHX8 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs550472362; called by muse, varscan2
- DIPK1B | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs565704797, COSV63038134; called by muse, mutect2, varscan2
- DLG5 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749395671, COSV64947470; called by muse, mutect2
- DOCK5 | c.4713dup p.T1572Yfs*10 | Frame Shift Ins (INS) | VAF 52/167 reads (31%) | catalogued as rs745668075; called by mutect2, varscan2
- DST | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 158/401 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.939); catalogued as rs750111800; called by muse, mutect2, varscan2
- DYSF | c.1661G>A p.G554D | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50288782; called by muse, mutect2, varscan2
- EHD1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs774644717, COSV57736009; called by muse, mutect2, varscan2
- EPAS1 | c.1024T>C p.Y342H | Missense Mutation (SNP) | VAF 27/627 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55384708; called by muse, mutect2
- EPHB6 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 113/706 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs1013473927; called by muse, mutect2, varscan2
- FAM118A | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 150/479 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.972); catalogued as COSV53415954; called by muse, mutect2, varscan2
- FAM120AOS | c.683del p.K228Rfs*22 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as COSV52905526; called by mutect2, pindel, varscan2
- FAM83E | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs748622195, COSV52377268; called by muse, mutect2, varscan2
- FAM83E | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770440961; called by muse, mutect2, varscan2
- FAT2 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs147663319; called by muse, mutect2, varscan2
- FBXL14 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 22/452 reads (5%) | catalogued as COSV100201473, COSV59335816; called by muse, mutect2
- FEM1B | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.362); catalogued as rs1195576004; called by muse, mutect2, varscan2
- FHOD3 | c.4006C>T p.R1336C (on ENST00000359247 / NM_001281739.3; = p.R1353C on NM_025135.5) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57183629; called by muse, mutect2, varscan2
- FIGN | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs1558994444, COSV100292529, COSV60772581; called by muse, mutect2, varscan2
- FLT3LG | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs377505124; called by muse, mutect2, varscan2
- FOXP4 | c.1417G>A p.A473T (on ENST00000307972 / NM_001012426.1; = p.A460T on NM_138457.3) | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57218116; called by muse, mutect2
- GHSR | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 107/458 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs121917883, CM061011, COSV53840296; called by muse, mutect2, varscan2
- GMIP | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs1252953908; called by muse, mutect2
- GPR25 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV58497631; called by muse, mutect2, varscan2
- HK2 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 157/537 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs746916892; called by muse, mutect2, varscan2
- IFT122 | c.2413C>T p.R805C (on ENST00000348417 / NM_052989.3; = p.R746C on NM_018262.4) | Missense Mutation (SNP) | VAF 38/624 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1413221093, COSV56205944; called by muse, mutect2
- IGF1R | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs201956526, COSV51393753; called by muse, mutect2, varscan2
- IGSF8 | c.479del p.P160Qfs*15 | Frame Shift Del (DEL) | VAF 52/226 reads (23%) | catalogued as rs754902711; called by mutect2, varscan2
- IRX1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs749695664; called by muse, mutect2, varscan2
- KALRN | c.2510A>G p.Q837R | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs112304715; called by muse, mutect2, varscan2
- KANSL3 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs370590181; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | catalogued as COSV54711577; called by mutect2, pindel
- KRT82 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.095); catalogued as rs372445184; called by muse, mutect2
- LPAR5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.172); catalogued as rs941588925; called by muse, mutect2
- LRIG3 | c.2993T>G p.L998R | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as rs1157545319; called by muse, mutect2, varscan2
- LRP4 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 190/722 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as rs545112106, COSV101066522; called by muse, varscan2
- LRRTM4 | c.1579T>C p.Y527H | Missense Mutation (SNP) | VAF 132/390 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV69160652; called by muse, mutect2, varscan2
- MAGEA4 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs775207650, COSV52341203; called by muse, mutect2, varscan2
- MAST1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs778952796; called by muse, mutect2, varscan2
- MUC2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs773602927; called by muse, mutect2, varscan2
- MYLK | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs376586087; called by muse, mutect2, varscan2
- MYO7B | c.5305C>T p.R1769C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs201912936; called by muse, mutect2, varscan2
- MYT1L | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 194/537 reads (36%) | catalogued as COSV67720421; called by muse, mutect2, varscan2
- N4BP3 | c.752_754del p.S251del | In Frame Del (DEL) | VAF 85/332 reads (26%) | catalogued as rs767128046; called by mutect2, pindel, varscan2
- NACA2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 196/684 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101478576, COSV71713103; called by muse, mutect2, varscan2
- NAGPA | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 34/386 reads (9%) | PolyPhen probably damaging (0.98); catalogued as rs377424631; called by muse, mutect2
- NEU4 | c.254T>C p.M85T (on ENST00000391969 / NM_001167602.3; = p.M97T on NM_080741.4) | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771243467; called by muse, mutect2
- NID1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs762941239, COSV51621005; called by muse, mutect2, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 50/171 reads (29%) | catalogued as rs751187638; called by mutect2, varscan2
- NOS2 | c.2093A>G p.Y698C | Missense Mutation (SNP) | VAF 113/402 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); catalogued as COSV58222716; called by muse, mutect2, varscan2
- P3H2 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs150007134; called by muse, mutect2
- PCDHB11 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 263/1086 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV61313774; called by muse, mutect2, varscan2
- PCDHB4 | c.916T>A p.L306M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1221553265, COSV99522119; called by muse, varscan2
- PHKA2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 190/721 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV66056390; called by muse, mutect2, varscan2
- PLA2G4D | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1298784877; called by muse, mutect2, varscan2
- POLR3H | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 222/678 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs201601310; called by muse, mutect2, varscan2
- POLRMT | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs559722442; called by muse, mutect2, varscan2
- PPL | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV52169516; called by muse, mutect2, varscan2
- PPP1R26 | c.3290dup p.R1098Qfs*60 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs764146060; called by mutect2, varscan2
- PRR5L | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs776348774; called by muse, mutect2, varscan2
- REC8 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs749657278, COSV61015230; called by muse, mutect2, varscan2
- RHCG | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs201496699, COSV99174380; called by muse, mutect2
- RNF32 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 109/459 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs770700325, COSV58731739; called by muse, mutect2, varscan2
- RPL7L1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 66/571 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs369621205; called by mutect2, varscan2
- RPS6KL1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs757078900; called by muse, mutect2, varscan2
- SCAI | c.758C>T p.S253L (on ENST00000336505 / NM_001144877.3; = p.S276L on NM_173690.5) | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1333350235, COSV60612563; called by muse, mutect2
- SDHD | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 19/660 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1566692479; ClinVar: uncertain significance; called by muse, mutect2
- SEMA3E | c.941dup p.L314Ffs*8 | Frame Shift Ins (INS) | VAF 18/120 reads (15%) | catalogued as rs751393345; called by mutect2, varscan2
- SLC25A53 | c.662A>T p.N221I | Missense Mutation (SNP) | VAF 79/586 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.162); catalogued as COSV62458260; called by muse, mutect2, varscan2
- SLIT2 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771378965; called by muse, mutect2, varscan2
- SMG6 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 29/313 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs748739928, COSV53977634; called by muse, mutect2
- SOX11 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV100431421; called by muse, mutect2, varscan2
- SRP54 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs749487051, COSV53740081; called by muse, mutect2, varscan2
- TBXT | c.381del p.D128Tfs*10 | Frame Shift Del (DEL) | VAF 128/485 reads (26%) | catalogued as COSV51619556; called by mutect2, pindel, varscan2
- TELO2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs774629694; called by muse, mutect2
- TEX2 | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51980712; called by muse, mutect2, varscan2
- TMC8 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1445609111; called by muse, mutect2
- TRAPPC13 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1174575049, COSV51556206; called by muse, mutect2, varscan2
- TRIML2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765811966; called by muse, mutect2, varscan2
- TUFM | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 152/1146 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV57949284; called by muse, mutect2, varscan2
- TYRO3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs758559401, COSV55486654; called by muse, mutect2, varscan2
- TYSND1 | c.1299C>T p.G433= | Splice Region (SNP) | VAF 36/135 reads (27%) | catalogued as rs573577892; called by muse, mutect2, varscan2
- UBTD2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs768061481; called by muse, mutect2, varscan2
- UNC5B | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533188246; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs749830910; called by mutect2, varscan2
- VPS13A | c.7082G>A p.R2361K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1372664900, COSV100652444; called by muse, mutect2, varscan2
- WBP1 | c.46dup p.A16Gfs*24 | Frame Shift Ins (INS) | VAF 21/158 reads (13%) | catalogued as rs752872580; called by mutect2, varscan2
- WDR87 | c.8159del p.K2720Rfs*57 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | catalogued as rs1555756562; called by mutect2, varscan2
- WDR90 | c.3550G>A p.A1184T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs376754744; called by muse, mutect2, varscan2
- WFIKKN2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 142/573 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as rs773779313; called by muse, mutect2, varscan2
- WRNIP1 | c.1839dup p.V614Rfs*11 | Frame Shift Ins (INS) | VAF 208/832 reads (25%) | catalogued as rs1334777007; called by mutect2, pindel, varscan2
- ZDHHC23 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248132766; called by muse, mutect2
- ZFP36L2 | c.791del p.P264Rfs*197 | Frame Shift Del (DEL) | VAF 126/379 reads (33%) | catalogued as COSV56698600, COSV56699248; called by mutect2, pindel, varscan2
- ZNF292 | c.4961_4963del p.T1654del | In Frame Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs772603421; called by pindel, varscan2
- ZNF546 | c.2315C>T p.T772M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780002612, COSV61257074; called by muse, mutect2, varscan2
- ZNF665 | c.961C>T p.H321Y (on ENST00000600412; = p.H386Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs749761595; called by muse, mutect2, varscan2
- ZNF74 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1277161186, COSV62620939; called by muse, mutect2, varscan2
- ZSCAN21 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1448604857, COSV52850859; called by muse, mutect2
- ABCF1 | c.2424G>T p.Q808H (on ENST00000326195 / NM_001025091.2; = p.Q770H on NM_001090.3) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ACSL3 | c.372dup p.K125* | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ACVR1B | c.1262-1G>T p.X421_splice | Splice Site (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- ACVRL1 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 77/513 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 142/676 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADPRHL1 | c.378del p.G127Afs*36 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- AGL | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- AMIGO3 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 54/998 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ANLN | c.1490T>A p.I497K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 33/257 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF6 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 72/486 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.4538G>A p.S1513N | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ARMCX2 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ATP7A | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNC2 | c.2852G>A p.R951K | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C17orf80 | c.1562del p.P521Lfs*11 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | called by mutect2, pindel, varscan2
- C1QL4 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 69/649 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- C2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 114/750 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9orf152 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CARS1 | c.1303A>G p.M435V | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- CBFA2T2 | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CCDC74B | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CELF4 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CHAT | c.45del p.K16Nfs*184 | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | called by mutect2, pindel
- CHRM3 | c.92del p.P31Rfs*44 | Frame Shift Del (DEL) | VAF 67/406 reads (17%) | called by mutect2, pindel, varscan2
- CMTR2 | c.1041del p.H349Ifs*3 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | called by mutect2, varscan2
- CPA1 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.093); called by muse, mutect2
- CPZ | c.983T>C p.L328P (on ENST00000360986 / NM_001014447.3; = p.L317P on NM_003652.3) | Missense Mutation (SNP) | VAF 87/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.1420T>C p.C474R | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX2 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- DDX39B | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 163/515 reads (32%) | called by muse, mutect2, varscan2
- DDX4 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- DDX53 | c.1423A>G p.S475G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEPDC5 | c.1037A>T p.D346V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIAPH2 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.009); called by muse, mutect2
- DISC1 | c.1047+2T>C p.X349_splice | Splice Site (SNP) | VAF 166/502 reads (33%) | called by mutect2, varscan2
- DNAH6 | c.10898del p.L3633* | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel, varscan2
- DNAI2 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 213/655 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DRGX | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECPAS | c.5308+2T>C p.X1770_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- EFEMP2 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 26/778 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- EMC2 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EML5 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMSY | c.3217A>C p.T1073P | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENHO | c.134_135dup p.E46Lfs*44 | Frame Shift Ins (INS) | VAF 114/419 reads (27%) | called by mutect2, varscan2
- ESPN | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 239/857 reads (28%) | called by muse, mutect2, varscan2
- ESYT1 | c.1783-1G>T p.X595_splice | Splice Site (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- F13A1 | c.2029dup p.M677Nfs*7 | Frame Shift Ins (INS) | VAF 105/847 reads (12%) | called by mutect2, pindel, varscan2
- FADD | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM111A | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171B | c.2399del p.G800Afs*5 | Frame Shift Del (DEL) | VAF 28/270 reads (10%) | called by mutect2, pindel
- FAM71A | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 154/450 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- FAM83E | c.1396T>C p.S466P | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR4 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- FOXP1 | c.1240del p.L414* | Frame Shift Del (DEL) | VAF 61/264 reads (23%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.1685A>G p.Q562R | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GBF1 | c.5394del p.D1799Tfs*11 (on ENST00000369983 / NM_001377137.1; = p.D1798Tfs*11 on NM_004193.3) | Frame Shift Del (DEL) | VAF 45/161 reads (28%) | called by mutect2, pindel, varscan2
- GCN1 | c.7087del p.V2363Cfs*3 | Frame Shift Del (DEL) | VAF 32/438 reads (7%) | called by mutect2, pindel
- GDNF | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GIMAP8 | c.762dup p.K255Efs*24 | Frame Shift Ins (INS) | VAF 91/357 reads (25%) | called by mutect2, pindel, varscan2
- GRIP2 | c.1687G>T p.G563C (on ENST00000619221; = p.G466C on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HAVCR1 | c.674-2A>G p.X225_splice | Splice Site (SNP) | VAF 11/249 reads (4%) | called by muse, mutect2
- HERPUD2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPA3 | c.67del p.E23Rfs*12 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, varscan2
- HSPBP1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by mutect2, varscan2
- IFNGR1 | c.672G>T p.W224C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFNL2 | c.449G>T p.R150M | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2
- INTS2 | c.3557G>A p.C1186Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ITPR3 | c.5472del p.T1825Pfs*30 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- JCAD | c.2182T>C p.S728P | Missense Mutation (SNP) | VAF 190/666 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KBTBD12 | c.246_247del p.S83Gfs*15 | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | called by pindel, varscan2
- KMT2D | c.6868G>T p.E2290* | Nonsense Mutation (SNP) | VAF 80/325 reads (25%) | called by muse, mutect2, varscan2
- KRBA1 | c.805_806insA p.L269Hfs*54 | Frame Shift Ins (INS) | VAF 74/298 reads (25%) | called by pindel, varscan2
- LAMA2 | c.5848C>A p.H1950N | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCA5 | c.1901T>A p.I634N | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDHB | c.1del p.M1? | Frame Shift Del (DEL) | VAF 58/350 reads (17%) | called by mutect2, pindel, varscan2
- LHFPL2 | c.338T>C p.M113T | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMNA | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- LPCAT3 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP4 | c.2362T>C p.Y788H | Missense Mutation (SNP) | VAF 160/766 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRRC40 | c.1343A>C p.K448T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LRRC49 | c.683A>C p.N228T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP3K4 | c.531del p.K177Nfs*30 | Frame Shift Del (DEL) | VAF 110/328 reads (34%) | called by pindel, varscan2
- MAPKBP1 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 16/333 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- METTL23 | c.381_386del p.L128_W129del | In Frame Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- MST1 | c.1502del p.G501Afs*25 | Frame Shift Del (DEL) | VAF 173/681 reads (25%) | called by mutect2, pindel, varscan2
- MTMR6 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH2 | c.2752A>C p.K918Q | Missense Mutation (SNP) | VAF 166/499 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO16 | c.1725dup p.Y576Ifs*31 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- MYO3B | c.1312_1313del p.S438Wfs*23 | Frame Shift Del (DEL) | VAF 101/354 reads (29%) | called by pindel, varscan2
- NDST1 | c.1481_1483del p.F494del | In Frame Del (DEL) | VAF 96/310 reads (31%) | called by pindel, varscan2
- NEUROD2 | c.1140del p.H381Ifs*164 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- NOS3 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OR1K1 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 154/461 reads (33%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- OR1M1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PARK7 | c.382_383del p.L128Cfs*2 | Frame Shift Del (DEL) | VAF 94/362 reads (26%) | called by pindel, varscan2
- PAXBP1 | c.1482A>C p.E494D | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PCDHGB5 | c.1064del p.N355Tfs*7 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- PCNX3 | c.1675del p.E559Sfs*24 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | called by mutect2, varscan2
- PGAP3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- PIK3R1 | c.1367_1378del p.F456_S460delinsC (on ENST00000521381 / NM_181523.3; = p.F186_S190delinsC on NM_181504.4) | In Frame Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- PIP5K1B | c.68del p.K23Rfs*15 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel
- PKN1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 79/314 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.1443dup p.V482Sfs*11 | Frame Shift Ins (INS) | VAF 10/110 reads (9%) | called by mutect2, pindel
- POLA1 | c.3158del p.K1053Rfs*25 | Frame Shift Del (DEL) | VAF 73/308 reads (24%) | called by mutect2, varscan2
- POU6F2 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPP1R8 | c.936C>G p.N312K (on ENST00000311772 / NM_014110.5; = p.N88K on NM_002713.4) | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 46/287 reads (16%) | called by mutect2, varscan2
- PREX1 | c.3386T>C p.L1129P | Missense Mutation (SNP) | VAF 119/490 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN23 | c.2249del p.P750Lfs*53 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | called by mutect2, pindel, varscan2
- PTPRQ | c.1781T>C p.M594T (on ENST00000616559; = p.M552T on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2
- RBM20 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 23/430 reads (5%) | called by muse, mutect2
- RESP18 | c.582del p.L195Wfs*3 | Frame Shift Del (DEL) | VAF 94/339 reads (28%) | called by mutect2, pindel, varscan2
- RNASET2 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 19/605 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2
- SEMA4C | c.2339del p.G780Vfs*15 | Frame Shift Del (DEL) | VAF 80/291 reads (27%) | called by mutect2, pindel, varscan2
- SIVA1 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.243); called by muse, mutect2
- SLC12A4 | c.2110C>A p.L704I | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.146); called by muse, mutect2
- SLC1A6 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 19/592 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2
- SORCS3 | c.3301del p.V1101Yfs*10 | Frame Shift Del (DEL) | VAF 53/185 reads (29%) | called by mutect2, pindel, varscan2
- SRC | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 15/399 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- STAG2 | c.2192T>G p.I731S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STARD7 | c.573del p.K191Nfs*6 | Frame Shift Del (DEL) | VAF 91/327 reads (28%) | called by mutect2, pindel, varscan2
- STARD9 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.24); called by muse, mutect2
- STK25 | c.97dup p.E33Gfs*8 | Frame Shift Ins (INS) | VAF 98/390 reads (25%) | called by mutect2, pindel, varscan2
- SYN2 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SYNE1 | c.19239_19240del p.E6413Dfs*14 (on ENST00000367255 / NM_182961.4; = p.E6342Dfs*14 on NM_033071.3) | Frame Shift Del (DEL) | VAF 114/414 reads (28%) | called by pindel, varscan2
- SZT2 | c.7891C>T p.R2631C (on ENST00000634258 / NM_001365999.1; = p.R2574C on NM_015284.4) | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.6463G>C p.A2155P | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- TET3 | c.3535_3537del p.E1179del | In Frame Del (DEL) | VAF 24/268 reads (9%) | called by mutect2, pindel
- TLR10 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS6 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 135/517 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TRAF3 | c.854del p.N285Tfs*38 | Frame Shift Del (DEL) | VAF 60/256 reads (23%) | called by mutect2, pindel, varscan2
- TRIM4 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIML2 | c.935del p.K312Rfs*34 | Frame Shift Del (DEL) | VAF 38/223 reads (17%) | called by mutect2, pindel, varscan2
- TRPM3 | c.3418A>G p.M1140V (on ENST00000357533 / NM_001366142.2; = p.M995V on NM_020952.6) | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2
- USP30 | c.582G>A p.Q194= | Splice Region (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- WAS | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WASHC2A | c.3848del p.K1283Rfs*53 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by mutect2, varscan2
- WDR5 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WDR54 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 59/438 reads (13%) | called by muse, mutect2, varscan2
- WNT6 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 41/665 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XPO7 | c.2431A>G p.N811D | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAN | c.6071C>A p.P2024H | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZCCHC7 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); called by muse, varscan2
- ZFP36L2 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFP82 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2
- ZKSCAN1 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF292 | c.452del p.L151* | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | called by mutect2, pindel, varscan2
- ZNF292 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZNF496 | c.206dup p.W70Lfs*5 | Frame Shift Ins (INS) | VAF 165/642 reads (26%) | called by mutect2, pindel, varscan2
- ZNF555 | c.1770dup p.Q591Tfs*3 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | called by mutect2, pindel
- ZNF628 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF646 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF726 | c.2134dup p.I712Nfs*6 | Frame Shift Ins (INS) | VAF 20/113 reads (18%) | called by mutect2, pindel, varscan2
- ZNF728 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZYX | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA2B | c.345C>T p.S115= | Silent (SNP) | VAF 126/359 reads (35%) | called by muse, mutect2, varscan2
- AGMAT | c.294G>A p.R98= | Silent (SNP) | VAF 107/363 reads (29%) | called by muse, mutect2
- APBA3 | c.711G>A p.P237= | Silent (SNP) | VAF 13/180 reads (7%) | catalogued as rs904382789; called by muse, mutect2
- APEX2 | c.123G>A p.A41= | Silent (SNP) | VAF 27/211 reads (13%) | catalogued as COSV100895148; called by muse, mutect2, varscan2
- ASB1 | c.669T>C p.N223= | Silent (SNP) | VAF 71/248 reads (29%) | catalogued as rs1226670178; called by muse, mutect2, varscan2
- ATG16L2 | c.423G>A p.Q141= | Silent (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- ATG5 | c.666T>C p.V222= | Silent (SNP) | VAF 50/196 reads (26%) | called by muse, varscan2
- ATP8A2 | c.2466C>T p.G822= | Silent (SNP) | VAF 78/296 reads (26%) | catalogued as rs764838044, COSV54953343; called by muse, mutect2, varscan2
- C2orf81 | c.438C>T p.H146= | Silent (SNP) | VAF 77/250 reads (31%) | catalogued as rs953107824; called by muse, mutect2, varscan2
- CACNG2 | c.723G>A p.S241= | Silent (SNP) | VAF 170/529 reads (32%) | catalogued as rs1569013846; called by muse, mutect2, varscan2
- CAMTA1 | c.771G>A p.P257= | Silent (SNP) | VAF 73/244 reads (30%) | catalogued as rs746398137; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC168 | c.20940T>C p.Y6980= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3933C>T p.H1311= | Silent (SNP) | VAF 115/491 reads (23%) | catalogued as rs760868480, COSV61348195; called by muse, mutect2, varscan2
- CLCN6 | c.1104G>A p.P368= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs773236964; called by muse, mutect2
- COL5A1 | c.1143C>A p.A381= | Silent (SNP) | VAF 38/588 reads (6%) | catalogued as COSV65676754; called by muse, mutect2
- DHX34 | c.3384C>T p.F1128= | Silent (SNP) | VAF 79/273 reads (29%) | catalogued as rs1240069579, COSV60895464; called by muse, mutect2, varscan2
- EGFLAM | c.228C>T p.G76= | Silent (SNP) | VAF 76/336 reads (23%) | catalogued as rs142461042; called by muse, mutect2, varscan2
- EMC1 | c.909G>A p.L303= | Silent (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- EPB41L1 | c.1614G>A p.L538= | Silent (SNP) | VAF 18/384 reads (5%) | catalogued as COSV52441386, COSV52442322; called by muse, mutect2
- FAM166B | c.399A>G p.P133= | Silent (SNP) | VAF 81/592 reads (14%) | called by muse, mutect2, varscan2
- FIGNL2 | c.474C>T p.Y158= | Silent (SNP) | VAF 64/210 reads (30%) | catalogued as rs981475968; called by mutect2, varscan2
- FRMD3 | c.1612C>T p.L538= | Silent (SNP) | VAF 129/591 reads (22%) | called by muse, mutect2, varscan2
- GDF7 | c.924G>A p.A308= | Silent (SNP) | VAF 81/307 reads (26%) | catalogued as rs756980908, COSV55347188; called by muse, mutect2, varscan2
- GJC2 | c.690C>T p.G230= | Silent (SNP) | VAF 26/704 reads (4%) | called by muse, mutect2
- GJD4 | c.720C>T p.S240= | Silent (SNP) | VAF 108/332 reads (33%) | catalogued as rs1329876204; called by muse, mutect2, varscan2
- GLI3 | c.3900G>A p.A1300= | Silent (SNP) | VAF 104/343 reads (30%) | catalogued as rs559754489, COSV67893266; called by muse, mutect2, varscan2
- GMIP | c.1071G>A p.P357= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.480C>T p.Y160= | Silent (SNP) | VAF 58/595 reads (10%) | catalogued as rs782639379; called by muse, mutect2, varscan2
- HIPK4 | c.1128G>A p.E376= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV99397267; called by muse, mutect2, varscan2
- HPS3 | c.2472G>A p.S824= | Silent (SNP) | VAF 58/240 reads (24%) | catalogued as rs201221505, COSV99937426; called by muse, mutect2, varscan2
- IFRD1 | c.81G>A p.T27= | Silent (SNP) | VAF 109/311 reads (35%) | catalogued as rs1333127742; called by muse, mutect2, varscan2
- KCNC2 | c.1629C>T p.D543= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as rs201944231; called by muse, mutect2, varscan2
- KCNK10 | c.1152G>A p.Q384= | Silent (SNP) | VAF 77/244 reads (32%) | catalogued as rs1412089611; called by muse, mutect2, varscan2
- LRP2 | c.10029C>T p.R3343= | Silent (SNP) | VAF 113/492 reads (23%) | catalogued as rs150166603; called by muse, mutect2, varscan2
- MBD3L3 | c.369C>T p.A123= | Silent (SNP) | VAF 272/1908 reads (14%) | catalogued as rs1316796421; called by muse, mutect2
- METTL7B | c.81C>T p.C27= | Silent (SNP) | VAF 85/287 reads (30%) | catalogued as rs761986095; called by muse, mutect2, varscan2
- MLF1 | c.90A>C p.I30= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- MTRR | c.2166T>C p.D722= (on ENST00000264668; = p.D695= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- MUCL3 | c.345T>C p.H115= | Silent (SNP) | VAF 100/379 reads (26%) | catalogued as rs1296496530; called by muse, mutect2, varscan2
- MYO18A | c.2931C>T p.R977= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as rs1373666600; called by muse, mutect2, varscan2
- NFIB | c.102G>A p.L34= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- NKAP | c.72G>A p.S24= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs745879274, COSV65056956; called by muse, mutect2, varscan2
- NLRP12 | c.630G>A p.P210= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as rs775052581, COSV60745228; called by muse, mutect2, varscan2
- NUBP2 | c.630C>T p.G210= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs377757202; called by muse, mutect2, varscan2
- OR52B2 | c.549T>C p.H183= | Silent (SNP) | VAF 24/392 reads (6%) | catalogued as rs7480755; called by muse, mutect2
- OTOG | c.4719C>T p.I1573= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- PAPLN | c.1566G>A p.L522= (on ENST00000554301; = p.L495= on NM_173462.4) | Silent (SNP) | VAF 121/428 reads (28%) | catalogued as rs1357977941; called by muse, mutect2, varscan2
- PCDHA12 | c.171G>A p.A57= | Silent (SNP) | VAF 275/842 reads (33%) | called by muse, mutect2, varscan2
- PCSK9 | c.960C>T p.D320= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as rs910368517, COSV56160374; ClinVar: likely benign; called by muse, mutect2
- PIK3R5 | c.975G>A p.E325= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs1323759848, COSV99353546; called by muse, mutect2
- PITPNM1 | c.453C>T p.G151= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs775935868; called by muse, mutect2
- PKHD1 | c.1308C>A p.T436= | Silent (SNP) | VAF 112/418 reads (27%) | called by muse, mutect2, varscan2
- PLCXD1 | c.255C>T p.S85= | Silent (SNP) | VAF 10/298 reads (3%) | catalogued as rs764882721, COSV101087949; called by muse, mutect2
- POU4F3 | c.789C>T p.N263= | Silent (SNP) | VAF 173/580 reads (30%) | catalogued as rs1561590706; called by muse, mutect2, varscan2
- PROB1 | c.1089G>A p.P363= | Silent (SNP) | VAF 156/462 reads (34%) | called by muse, mutect2, varscan2
- PRSS53 | c.1494C>T p.F498= | Silent (SNP) | VAF 20/371 reads (5%) | catalogued as rs957670736, COSV54926659; called by muse, mutect2
- PTPN21 | c.3348C>T p.G1116= | Silent (SNP) | VAF 127/525 reads (24%) | catalogued as rs75392975; called by muse, mutect2, varscan2
- PTPRH | c.3180G>A p.P1060= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs769586690, COSV54750776; called by muse, mutect2, varscan2
- RESP18 | c.111C>T p.R37= | Silent (SNP) | VAF 48/210 reads (23%) | catalogued as rs1465340708; called by muse, mutect2, varscan2
- RIMS2 | c.267G>A p.A89= | Silent (SNP) | VAF 155/543 reads (29%) | catalogued as rs780523576; called by muse, mutect2, varscan2
- RPS19 | c.405C>T p.A135= | Silent (SNP) | VAF 110/390 reads (28%) | catalogued as rs550819306, COSV55744040; called by muse, mutect2, varscan2
- SBNO2 | c.1572C>T p.I524= | Silent (SNP) | VAF 17/263 reads (6%) | catalogued as rs745368963, COSV62324936; called by muse, mutect2
- SCN11A | c.381C>A p.V127= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- SEMA3F | c.2172G>A p.T724= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs973475601; called by muse, mutect2
- SETX | c.6597C>T p.C2199= | Silent (SNP) | VAF 76/302 reads (25%) | called by muse, mutect2, varscan2
- SLC22A8 | c.690C>T p.Y230= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as rs372691932, COSV60326169; called by muse, mutect2, varscan2
- SLC25A24 | c.561C>T p.D187= | Silent (SNP) | VAF 34/287 reads (12%) | catalogued as rs368890665; called by muse, mutect2, varscan2
- SLITRK2 | c.42C>T p.A14= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV59427981; called by muse, mutect2, varscan2
- SNAPC4 | c.1305C>T p.S435= | Silent (SNP) | VAF 24/372 reads (6%) | catalogued as rs756653118, COSV53730612; called by muse, mutect2
- SNX18 | c.507C>T p.G169= | Silent (SNP) | VAF 66/222 reads (30%) | called by muse, mutect2, varscan2
- SORBS2 | c.1437G>A p.Q479= | Silent (SNP) | VAF 20/431 reads (5%) | called by muse, mutect2
- SOX11 | c.981G>A p.A327= | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as COSV58986350; called by muse, mutect2, varscan2
- SPANXD | c.111T>G p.P37= | Silent (SNP) | VAF 152/839 reads (18%) | called by muse, mutect2, varscan2
- SPEG | c.5478G>A p.R1826= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- SPSB4 | c.210C>T p.D70= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as rs755245292; called by muse, mutect2, varscan2
- SRCAP | c.4864C>T p.L1622= | Silent (SNP) | VAF 130/477 reads (27%) | catalogued as rs1238293217; called by muse, mutect2, varscan2
- STING1 | c.591G>A p.R197= | Silent (SNP) | VAF 15/416 reads (4%) | called by muse, mutect2
- STK40 | c.540C>T p.D180= | Silent (SNP) | VAF 82/302 reads (27%) | catalogued as rs770326216; called by muse, mutect2, varscan2
- TAOK2 | c.672G>A p.P224= | Silent (SNP) | VAF 105/373 reads (28%) | catalogued as rs1484863308; called by muse, mutect2, varscan2
- TECTA | c.5487C>A p.G1829= | Silent (SNP) | VAF 212/688 reads (31%) | catalogued as COSV50713935; called by mutect2, varscan2
- TERB1 | c.870A>G p.V290= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1203447499; called by muse, mutect2, varscan2
- TM4SF19 | c.629G>A p.*210= | Silent (SNP) | VAF 63/435 reads (14%) | called by muse, mutect2, varscan2
- TRIL | c.2319G>A p.A773= | Silent (SNP) | VAF 71/333 reads (21%) | catalogued as rs1463291310; called by muse, mutect2, varscan2
- TSC2 | c.1980C>T p.S660= | Silent (SNP) | VAF 99/456 reads (22%) | catalogued as rs959705365; ClinVar: likely benign; called by muse, varscan2
- TUBE1 | c.495C>T p.D165= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs79553536; called by muse, mutect2, varscan2
- TUBGCP5 | c.1257A>G p.G419= | Silent (SNP) | VAF 28/576 reads (5%) | called by muse, mutect2
- UNC13A | c.2541C>T p.D847= | Silent (SNP) | VAF 63/270 reads (23%) | catalogued as rs565106177, COSV53198157; called by muse, mutect2, varscan2
- UNK | c.210G>C p.R70= | Silent (SNP) | VAF 138/536 reads (26%) | catalogued as COSV53142130; called by muse, mutect2, varscan2
- UROD | c.309C>A p.G103= | Silent (SNP) | VAF 16/484 reads (3%) | called by muse, mutect2
- XYLB | c.126T>C p.D42= | Silent (SNP) | VAF 11/162 reads (7%) | catalogued as rs1404856241; called by muse, mutect2
- ZADH2 | c.804A>G p.V268= | Silent (SNP) | VAF 60/242 reads (25%) | called by muse, mutect2, varscan2
- ZFAT | c.864C>T p.A288= | Silent (SNP) | VAF 16/281 reads (6%) | called by muse, mutect2
- ZNF100 | c.1197A>G p.K399= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- ZNF799 | c.1680T>C p.Y560= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV101345302; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | chr3:51989106 G>T | 3'Flank (SNP) | VAF 24/379 reads (6%) | called by muse, mutect2
- AC073348.1 | n.80A>T | RNA (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- AL139039.3 | chr6:10509135 G>A | 3'Flank (SNP) | VAF 41/284 reads (14%) | catalogued as rs764656378, COSV68413017; called by muse, mutect2, varscan2
- ARHGAP33 | c.502-357G>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs765769669, COSV50137739; called by muse, mutect2, varscan2
- ARMC5 | c.1865-21T>C | Intron (SNP) | VAF 52/322 reads (16%) | called by muse, mutect2, varscan2
- C11orf65 | c.*1210del | 3'UTR (DEL) | VAF 26/100 reads (26%) | called by mutect2, varscan2
- CARD19 | c.*819G>A | 3'UTR (SNP) | VAF 69/257 reads (27%) | catalogued as rs769238763, COSV64936034; called by muse, mutect2, varscan2
- CD81 | c.66+1570T>C | Intron (SNP) | VAF 62/318 reads (19%) | called by muse, varscan2
- COG1 | c.2511-34del | Intron (DEL) | VAF 22/310 reads (7%) | called by mutect2, pindel
- COMMD1 | c.180+9871T>C | Intron (SNP) | VAF 76/238 reads (32%) | called by muse, mutect2, varscan2
- CRAT | c.-11G>A | 5'UTR (SNP) | VAF 66/164 reads (40%) | catalogued as rs748899552; called by muse, mutect2, varscan2
- CSN1S2AP | n.405G>A | RNA (SNP) | VAF 64/218 reads (29%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+230G>T | Intron (SNP) | VAF 67/517 reads (13%) | called by muse, mutect2, varscan2
- DRD2 | c.723+39C>T | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- FMN1 | c.2044-2039A>C | Intron (SNP) | VAF 47/407 reads (12%) | called by muse, mutect2, varscan2
- GDAP1 | c.*91G>T | 3'UTR (SNP) | VAF 256/852 reads (30%) | called by muse, mutect2, varscan2
- GIGYF2 | c.532+6744del | Intron (DEL) | VAF 19/104 reads (18%) | called by mutect2, varscan2
- GPC1 | c.167-8341del | Intron (DEL) | VAF 44/169 reads (26%) | catalogued as rs563795742; called by mutect2, varscan2
- GTPBP2 | c.*182C>T | 3'UTR (SNP) | VAF 31/212 reads (15%) | called by muse, mutect2, varscan2
- HSPA7 | n.232C>T | RNA (SNP) | VAF 127/577 reads (22%) | called by muse, mutect2, varscan2
- IRAK4 | c.*57del | 3'UTR (DEL) | VAF 14/56 reads (25%) | catalogued as rs755909125; called by mutect2, pindel
- LGALS8 | c.523-28T>C | Intron (SNP) | VAF 34/158 reads (22%) | catalogued as rs367596904; called by muse, mutect2
- LRBA | c.6363+8783C>T | Intron (SNP) | VAF 16/406 reads (4%) | called by muse, mutect2
- LRBA | c.6363+8278C>T | Intron (SNP) | VAF 36/134 reads (27%) | catalogued as rs1206905643; called by muse, mutect2
- MARCKS | c.*5G>A | 3'UTR (SNP) | VAF 44/155 reads (28%) | catalogued as rs1444169803; called by muse, mutect2, varscan2
- MRPL30 | c.-6A>G | 5'UTR (SNP) | VAF 63/227 reads (28%) | called by muse, mutect2, varscan2
- MXRA8 | c.478+24del | Intron (DEL) | VAF 63/206 reads (31%) | called by mutect2, pindel, varscan2
- Metazoa_SRP | chr15:62246608 G>A | 5'Flank (SNP) | VAF 40/315 reads (13%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-2800G>A | Intron (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2
- NPHP1 | c.1926+352del | Intron (DEL) | VAF 22/116 reads (19%) | catalogued as rs112428035; called by mutect2, varscan2
- OR2W5 | n.712G>A | RNA (SNP) | VAF 21/456 reads (5%) | called by muse, mutect2
- PAFAH1B1 | c.1160-38C>T | Intron (SNP) | VAF 44/176 reads (25%) | catalogued as rs771577108; called by muse, mutect2, varscan2
- POM121C | chr7:75416045 C>A | 3'Flank (SNP) | VAF 108/517 reads (21%) | called by muse, mutect2, varscan2
- RAB5A | c.*472A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs996479516; called by muse, mutect2
- RIPOR2 | c.1921-357del | Intron (DEL) | VAF 27/92 reads (29%) | catalogued as rs752301269; called by mutect2, varscan2
- RN7SL484P | chr15:99790533 del A | 5'Flank (DEL) | VAF 20/76 reads (26%) | catalogued as rs1270396760; called by mutect2, varscan2
- RNF217-AS1 | n.1618C>T | RNA (SNP) | VAF 57/186 reads (31%) | called by muse, mutect2, varscan2
- RPL3 | c.952-145C>T | Intron (SNP) | VAF 36/310 reads (12%) | called by muse, mutect2, varscan2
- SCN4B | c.*2330T>A | 3'UTR (SNP) | VAF 110/392 reads (28%) | catalogued as rs1445145488, COSV100228811; called by mutect2, varscan2
- SFTPA1 | c.*922del | 3'UTR (DEL) | VAF 30/118 reads (25%) | catalogued as rs763121640; called by mutect2, varscan2
- SIL1 | c.-1T>C | 5'UTR (SNP) | VAF 173/810 reads (21%) | catalogued as rs866405224; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20205del | Intron (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel
- STK32C | c.319-31G>A | Intron (SNP) | VAF 27/444 reads (6%) | called by muse, mutect2
- TNFRSF10B | c.*1224dup | 3'UTR (INS) | VAF 200/777 reads (26%) | called by mutect2, pindel, varscan2
- TNS1 | c.-178dup | 5'UTR (INS) | VAF 26/351 reads (7%) | called by mutect2, pindel
- TRIML2 | c.621+18del | Intron (DEL) | VAF 15/167 reads (9%) | called by mutect2, pindel
- TSPAN7 | c.82-10114T>C | Intron (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- ZNF76 | c.1608+80T>G | Intron (SNP) | VAF 17/333 reads (5%) | called by muse, mutect2
- ZNF829 | c.-51C>T | 5'UTR (SNP) | VAF 53/218 reads (24%) | catalogued as COSV61742545; called by muse, mutect2, varscan2
